Gene-level copy-number profile of tumor specimen TARGET-40-0A4I0Q-01A from TARGET case TARGET-40-0A4I0Q, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 19.9 years (7,269 days).
Specimen TARGET-40-0A4I0Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.5fe8b5b3-2251-5dd3-a7b3-8d72c4994f59.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I0Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate.
https://portal.gdc.cancer.gov/files/c793c051-8d61-43c3-870c-5f606ddc7ccb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 16,615; copy number 2: 38,795; copy number 3: 3,312; copy number 4: 466; copy number 5: 368; copy number 7: 24; copy number 9: 12; copy number 11: 3; copy number 13: 25; copy number 16: 23; copy number 18: 26; copy number 19: 41; copy number 21: 6; copy number 26: 17; copy number 35: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,565,654–152,601,086, 3 genes: LCE3E, LCE3D, LCE3C.
- chr5:180,967,189–180,982,611, 3 genes: AC091874.2, AC091874.1, ARPP19P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 546 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:9,363,275–9,422,481, 1 gene, copy number 5 (within-gene range 3–5): AC091906.1.
- chr5:21,323,873–22,853,344, 13 genes, copy number 5 (within-gene range 3–5): AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1.
- chr5:23,951,348–24,353,443, 7 genes, copy number 5: C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1.
- chr5:25,909,503–25,990,687, 2 genes, copy number 5 (within-gene range 4–5): MSNP1, AC113370.1.
- chr5:26,669,346–27,496,994, 9 genes, copy number 5: AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1.
- chr5:42,423,439–43,192,021, 24 genes, copy number 7: GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3.
- chr6:74,004,520–74,850,484, 7 genes, copy number 19–21: TXNP7, AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2, AL356473.1.
- chr8:38,099,471–38,853,028, 30 genes, copy number 5: AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2.
- chr12:37,575,587–39,908,300, 27 genes, copy number 11–35 (within-gene range 2–35): ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40.
- chr12:39,819,750–39,819,883, 1 gene, copy number 16: AC121336.1.
- chr12:57,591,174–59,436,874, 49 genes, copy number 13–26 (within-gene range 2–26): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P.
- chr12:65,824,460–68,850,686, 68 genes, copy number 9–19 (broad region; genes not listed).
- chr18:26,454,910–26,657,401, 5 genes, copy number 5 (within-gene range 3–5): KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P.
- chr18:26,685,954–26,825,171, 4 genes, copy number 5: AC012588.1, PCAT18, U3, AC018371.1.
- chr19:8,832,398–13,906,452, 297 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:1,561,385–1,620,061, 2 genes, copy number 11 (within-gene range 1–11): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 15,090. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
